Somatic mutation profile of tumor specimen TCGA-D8-A147-01A (aliquot TCGA-D8-A147-01A-11D-A10Y-09) from TCGA case TCGA-D8-A147, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 45.8 years (16,736 days).
Specimen TCGA-D8-A147-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa0c96fc-2559-43cd-aaf7-4b6d05b0abc8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A147-10A (Blood Derived Normal), aliquot TCGA-D8-A147-10A-01D-A110-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/895c59c8-b306-41d5-a242-4e221b018492

The open-access MAF lists 163 somatic variants for this specimen: 133 protein-altering or splice-affecting, 30 silent.
By variant classification: Missense Mutation 117, Silent 30, Nonsense Mutation 7, Frame Shift Del 5, In Frame Del 2, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 41/71 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A4GALT | c.642C>G p.Y214* | Nonsense Mutation (SNP) | VAF 13/18 reads (72%) | catalogued as COSV50744925; called by muse, mutect2, varscan2
- AARS1 | c.445G>C p.D149H | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55749444; called by muse, mutect2
- ALG13 | c.3328C>G p.Q1110E | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV52641505; called by muse, mutect2, varscan2
- ANKRD26 | c.2827T>G p.F943V | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV65776544; called by muse, mutect2, varscan2
- ASB1 | c.737A>C p.H246P | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV52827437; called by muse, mutect2, varscan2
- BEND2 | c.2038G>T p.A680S | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV101191952, COSV66216226; called by muse, mutect2
- BIRC5 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 11/185 reads (6%) | catalogued as COSV100051308; called by muse, mutect2
- BLOC1S5 | c.445A>C p.M149L | Missense Mutation (SNP) | VAF 52/249 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV55242159; called by muse, mutect2, varscan2
- BTBD7 | c.2995C>T p.P999S | Missense Mutation (SNP) | VAF 93/149 reads (62%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.033); catalogued as COSV58288292; called by muse, mutect2, varscan2
- CACNA2D1 | c.3007T>A p.F1003I (on ENST00000356253 / NM_001366867.1; = p.F991I on NM_000722.4) | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.478); catalogued as COSV62384020; called by muse, mutect2, varscan2
- CAMSAP2 | c.3037C>G p.P1013A (on ENST00000236925 / NM_001297707.2; = p.P1002A on NM_203459.3) | Missense Mutation (SNP) | VAF 86/168 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV52673364; called by muse, mutect2, varscan2
- CCDC150 | c.1308G>C p.Q436H | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.471); catalogued as COSV55876123; called by muse, mutect2, varscan2
- CCDC185 | c.590C>G p.S197W | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100838793, COSV64822026; called by muse, mutect2
- CCDC22 | c.298C>G p.L100V | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.362); catalogued as COSV100879771; called by muse, mutect2
- CD163L1 | c.2954G>C p.G985A | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58019425; called by muse, mutect2, varscan2
- CELSR2 | c.4276G>T p.V1426F | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99603647; called by muse, mutect2, varscan2
- CIC | c.1744G>C p.A582P | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); catalogued as COSV50610140; called by muse, mutect2, varscan2
- CKLF-CMTM1 | c.156A>T p.E52D | Missense Mutation (SNP) | VAF 119/239 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV50451448; called by muse, mutect2, varscan2
- CNBD1 | c.420C>G p.I140M | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101572878; called by muse, mutect2
- CNTNAP2 | c.2318G>C p.G773A | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.642); catalogued as rs756029588, COSV62185175, COSV62212107; called by muse, mutect2, varscan2
- COPS2 | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV54646071; called by muse, mutect2, varscan2
- CPNE1 | c.805G>C p.E269Q (on ENST00000352393; = p.E274Q on NM_003915.5) | Missense Mutation (SNP) | VAF 18/291 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.028); catalogued as COSV100467373; called by muse, mutect2
- CRYBG1 | c.2464G>A p.D822N | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.024); catalogued as COSV64813069; called by muse, mutect2, varscan2
- DCLK2 | c.1537C>A p.H513N | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99651818; called by muse, mutect2
- DDR2 | c.2021C>A p.S674Y | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV63372276; called by muse, mutect2, varscan2
- DDX42 | c.999T>A p.C333* | Nonsense Mutation (SNP) | VAF 11/226 reads (5%) | catalogued as COSV100834899; called by muse, mutect2
- DEFB1 | c.8C>A p.T3N | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.202); catalogued as COSV52413107; called by muse, mutect2, varscan2
- DMGDH | c.1510C>T p.Q504* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as rs746100635, COSV54865786; called by muse, mutect2, varscan2
- DNAH7 | c.329C>G p.S110C | Missense Mutation (SNP) | VAF 177/296 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV56773156; called by muse, mutect2, varscan2
- DYNC2H1 | c.11468A>T p.Q3823L | Missense Mutation (SNP) | VAF 97/126 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV62099053; called by muse, mutect2, varscan2
- EPHB1 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67669953; called by muse, mutect2
- ESAM | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54034261, COSV54035755; called by muse, mutect2, varscan2
- EXOC6 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as COSV53327691; called by muse, mutect2, varscan2
- EXOC7 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as COSV58740338; called by muse, mutect2
- FAM135A | c.3130G>T p.G1044C (on ENST00000370479 / NM_001351599.1; = p.G831C on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762402721, COSV52054396; called by muse, mutect2, varscan2
- FAM135B | c.307G>T p.A103S | Missense Mutation (SNP) | VAF 66/191 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.288); catalogued as rs369404911, COSV50523175; called by muse, mutect2, varscan2
- FAT3 | c.7183A>T p.N2395Y | Missense Mutation (SNP) | VAF 62/94 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99964964; called by muse, mutect2, varscan2
- FBLN1 | c.1905C>A p.D635E | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.081); catalogued as COSV59939357; called by muse, mutect2, varscan2
- FBXL4 | c.416C>G p.A139G | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs770564931, COSV57748022; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGD6 | c.2613A>C p.K871N | Missense Mutation (SNP) | VAF 58/251 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59694675; called by muse, mutect2, varscan2
- FRAS1 | c.6793G>C p.D2265H | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV99350858; called by muse, mutect2
- FRMD7 | c.179T>A p.L60* | Nonsense Mutation (SNP) | VAF 12/111 reads (11%) | catalogued as COSV53747334; called by muse, mutect2, varscan2
- FTSJ3 | c.431C>G p.A144G | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.651); catalogued as COSV100037288; called by muse, mutect2
- GCC2 | c.4835C>G p.S1612C | Missense Mutation (SNP) | VAF 45/1248 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100565399, COSV59180005; called by muse, mutect2
- GFPT2 | c.1006T>G p.S336A | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV53809889; called by muse, mutect2, varscan2
- GFRA1 | c.1049A>G p.D350G | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100815660; called by muse, mutect2
- GIMAP6 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs372474469; called by muse, mutect2, varscan2
- GOLGB1 | c.1616C>A p.S539Y | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (1); PolyPhen possibly damaging (0.568); catalogued as COSV61467706; called by muse, varscan2
- HIF3A | c.1036G>C p.E346Q (on ENST00000377670 / NM_152795.4; = p.E277Q on NM_022462.4) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.159); catalogued as COSV52201078; called by muse, mutect2, varscan2
- HLA-F | c.695C>G p.A232G | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.593); catalogued as COSV52576331; called by muse, mutect2, varscan2
- IFI44L | c.1213G>C p.A405P | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV60728346; called by muse, mutect2, varscan2
- IGSF21 | c.301G>T p.V101L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.029); catalogued as COSV52137560; called by muse, mutect2, varscan2
- INTS3 | c.1870G>A p.E624K | Missense Mutation (SNP) | VAF 135/257 reads (53%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.953); catalogued as COSV59679317; called by muse, mutect2, varscan2
- INTS3 | c.2011C>G p.L671V | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV100015889; called by muse, mutect2
- IP6K3 | c.150C>G p.F50L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as rs779000873, COSV53390907; called by muse, mutect2, varscan2
- KALRN | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.997); catalogued as rs377636182; called by muse, mutect2, varscan2
- KCNH6 | c.144C>G p.F48L | Missense Mutation (SNP) | VAF 41/223 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV59005101; called by muse, mutect2, varscan2
- KCNS2 | c.359G>T p.S120I | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.601); catalogued as COSV99751072; called by muse, mutect2, varscan2
- LGR4 | c.539A>G p.Q180R | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.782); catalogued as COSV64865031; called by muse, mutect2, varscan2
- LMTK2 | c.3512C>G p.S1171C | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV51999156; called by muse, mutect2, varscan2
- LOXL3 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs762811068, COSV51206335; called by muse, mutect2, varscan2
- LRP2 | c.8527G>C p.D2843H | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99787923; called by muse, mutect2
- LRRIQ1 | c.4453T>A p.F1485I | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV67833735; called by muse, mutect2, varscan2
- LY9 | c.488C>G p.S163C | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1475702551, COSV99626574; called by muse, mutect2
- MAGEC1 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); catalogued as COSV53568020, COSV53576550; called by muse, mutect2, varscan2
- MAGEE1 | c.1190C>G p.P397R | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV63910970; called by muse, mutect2, varscan2
- MCRS1 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV59460386; called by muse, mutect2, varscan2
- MERTK | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 27/374 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs766215580, COSV99774495; called by muse, mutect2
- MORC2 | c.570G>C p.K190N (on ENST00000397641 / NM_001303256.3; = p.K128N on NM_014941.3) | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV53200181; called by muse, mutect2, varscan2
- MRC1 | c.266A>G p.Y89C | Missense Mutation (SNP) | VAF 78/323 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs369459730; called by muse, mutect2
- MTCH1 | c.1070T>C p.I357T (on ENST00000373627 / NM_001271641.1; = p.I340T on NM_014341.2) | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.702); catalogued as COSV65320996; called by muse, mutect2, varscan2
- MXRA5 | c.1834A>T p.I612F | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV54241249; called by muse, mutect2, varscan2
- MYC | c.1246G>A p.E416K (on ENST00000377970; = p.E431K on NM_002467.6) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.185); catalogued as COSV52375589; called by muse, mutect2, varscan2
- MYH7 | c.5638C>T p.R1880C | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1057522617, COSV62521351; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO7B | c.1791A>C p.L597F | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.588); catalogued as COSV67349140; called by muse, mutect2, varscan2
- NDRG1 | c.734G>C p.G245A | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.15); catalogued as COSV60484842; called by muse, mutect2, varscan2
- NELL1 | c.1735A>G p.S579G | Missense Mutation (SNP) | VAF 56/201 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.68); catalogued as rs370919301; called by muse, mutect2, varscan2
- NHLRC1 | c.538G>T p.V180F | Missense Mutation (SNP) | VAF 29/219 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100513457; called by muse, mutect2, varscan2
- OR10T2 | c.548C>A p.A183E | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.796); catalogued as COSV57782197; called by muse, mutect2, varscan2
- OR2T34 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 52/530 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0.101); catalogued as COSV100170350; called by muse, mutect2
- OR4X2 | c.277del p.L93Ffs*17 | Frame Shift Del (DEL) | VAF 36/197 reads (18%) | catalogued as COSV56584145, COSV56585069; called by mutect2, pindel, varscan2
- OR5I1 | c.769C>T p.L257F | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV56887899, COSV56889381; called by muse, mutect2, varscan2
- PAX3 | c.1430G>T p.W477L | Missense Mutation (SNP) | VAF 11/176 reads (6%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV100399481; called by muse, mutect2
- PCNT | c.7199G>C p.R2400P | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as COSV100855395, COSV64027236; called by muse, mutect2
- PDE4B | c.2007G>T p.R669S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.006); catalogued as COSV58479373; called by muse, mutect2, varscan2
- PDLIM7 | c.1210G>C p.D404H | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63081482; called by muse, mutect2, varscan2
- PEBP1 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.141); catalogued as COSV54337401; called by muse, mutect2, varscan2
- PEG3 | c.4593C>G p.I1531M | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as rs779244604, COSV55629050, COSV55638960; called by muse, mutect2, varscan2
- PLXNA3 | c.3663G>A p.M1221I | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63754965; called by muse, mutect2
- PPIP5K2 | c.3480G>C p.K1160N (on ENST00000358359 / NM_001276277.3; = p.K1139N on NM_015216.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.028); catalogued as COSV58607136; called by muse, mutect2, varscan2
- PPP2CB | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.235); catalogued as COSV55328958; called by muse, mutect2, varscan2
- PRAG1 | c.4196C>T p.S1399L | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV58163706; called by muse, mutect2, varscan2
- PSG4 | c.500T>C p.L167S | Missense Mutation (SNP) | VAF 26/684 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99736855; called by muse, mutect2
- PXYLP1 | c.130C>G p.R44G | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99649158, COSV99649386; called by muse, mutect2
- RABGGTB | c.221T>A p.F74Y | Missense Mutation (SNP) | VAF 65/226 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.096); catalogued as COSV60638188; called by muse, mutect2, varscan2
- RBM6 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.041); catalogued as rs746775897, COSV56484939; called by muse, mutect2, varscan2
- RPL27 | c.350A>C p.K117T | Missense Mutation (SNP) | VAF 11/177 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.063); catalogued as COSV99518477; called by muse, mutect2
- SCN11A | c.998T>C p.I333T | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV56573361; called by muse, mutect2, varscan2
- SCYL2 | c.2010G>C p.Q670H | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as COSV62569533; called by muse, mutect2, varscan2
- SEC16B | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV100381499; called by muse, mutect2, varscan2
- SETBP1 | c.4762C>G p.R1588G | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as CM1212389, COSV56328307, COSV56337748; called by muse, mutect2, varscan2
- SNX8 | c.685T>C p.Y229H | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV56128061; called by muse, mutect2, varscan2
- SPAG9 | c.1126G>C p.D376H (on ENST00000262013 / NM_001130528.3; = p.D362H on NM_003971.6) | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.365); catalogued as rs1319204520, COSV56238564; called by muse, mutect2, varscan2
- SPOP | c.601G>C p.D201H | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61654664; called by muse, mutect2, varscan2
- SPRTN | c.1094C>G p.S365C | Missense Mutation (SNP) | VAF 40/223 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV50478675; called by muse, mutect2, varscan2
- SPTBN5 | c.10360G>C p.D3454H | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58023731; called by muse, mutect2, varscan2
- SRP68 | c.119A>G p.E40G | Missense Mutation (SNP) | VAF 65/121 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs747691330, COSV57163525; called by muse, mutect2, varscan2
- SRPK1 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 121/257 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV60414112; called by muse, mutect2, varscan2
- ST8SIA6 | c.885G>T p.K295N | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as COSV66469738; called by muse, mutect2, varscan2
- STX12 | c.354G>T p.Q118H | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64249581; called by muse, mutect2, varscan2
- TPD52L1 | c.368A>G p.K123R | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV59192660; called by muse, mutect2, varscan2
- TRIM6 | c.189C>G p.Y63* | Nonsense Mutation (SNP) | VAF 32/149 reads (21%) | catalogued as COSV53477189; called by muse, mutect2, varscan2
- TRMT61B | c.377C>T p.S126L | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs375238952; called by muse, mutect2, varscan2
- TSC2 | c.1273A>T p.N425Y | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1186443300, COSV54770388; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTC3 | c.2588G>A p.R863K | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV100695256, COSV61287246, COSV61292926; called by muse, mutect2, varscan2
- TTC6 | c.676T>C p.F226L (on ENST00000267368; = p.F1592L on NM_001310135.3) | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.403); catalogued as COSV99941785; called by muse, mutect2
- TTN | c.63060G>C p.M21020I (on ENST00000591111; = p.M13596I on NM_003319.4) | Missense Mutation (SNP) | VAF 30/237 reads (13%) | PolyPhen benign (0); catalogued as COSV60172355; called by muse, mutect2, varscan2
- USP34 | c.4336G>C p.A1446P | Missense Mutation (SNP) | VAF 15/214 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.329); catalogued as COSV101276923; called by muse, mutect2
- WFDC6 | c.11C>A p.S4* | Nonsense Mutation (SNP) | VAF 26/190 reads (14%) | catalogued as rs553341164, COSV60549073; called by muse, varscan2
- ZNF239 | c.323A>C p.K108T | Missense Mutation (SNP) | VAF 36/381 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV100021780; called by muse, mutect2
- ZNF512 | c.750G>T p.K250N | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100820759; called by muse, mutect2
- ZNF512B | c.569A>T p.K190M | Missense Mutation (SNP) | VAF 42/259 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.049); catalogued as COSV53873695; called by muse, mutect2, varscan2
- ZNF536 | c.2537C>T p.P846L | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV62827961; called by muse, mutect2, varscan2
- CSMD3 | c.1422_1424dup p.L474_N475insK (on ENST00000297405 / NM_001363185.1; = p.L370_N371insK on NM_052900.3) | In Frame Ins (INS) | VAF 23/150 reads (15%) | called by mutect2, pindel, varscan2
- DOCK5 | c.4045_4059del p.Y1349_I1353del | In Frame Del (DEL) | VAF 29/95 reads (31%) | called by mutect2, pindel, varscan2
- EDAR | c.100_105del p.N34_E35del | In Frame Del (DEL) | VAF 10/92 reads (11%) | called by mutect2, pindel, varscan2
- GRHL3 | c.1199G>T p.C400F (on ENST00000350501 / NM_198174.3; = p.C405F on NM_021180.3) | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); called by muse, mutect2
- LATS1 | c.2759_2769del p.E920Afs*9 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | called by mutect2, pindel, varscan2
- MINDY4 | c.643_663+5del p.X215_splice | Splice Site (DEL) | VAF 46/103 reads (45%) | called by mutect2, pindel, varscan2
- PKHD1L1 | c.9880+1del | Frame Shift Del (DEL) | VAF 74/242 reads (31%) | called by mutect2, pindel, varscan2
- SPEG | c.3096_3118del p.E1033Lfs*9 | Frame Shift Del (DEL) | VAF 8/53 reads (15%) | called by mutect2, pindel, varscan2
- ST6GALNAC2 | c.827_846del p.H276Pfs*12 | Frame Shift Del (DEL) | VAF 32/259 reads (12%) | called by mutect2, pindel
- ABCC3 | c.1308G>A p.Q436= | Silent (SNP) | VAF 14/170 reads (8%) | catalogued as COSV53328619; called by muse, mutect2
- AL035461.3 | c.2724G>A p.S908= | Silent (SNP) | VAF 60/346 reads (17%) | catalogued as rs773179333, COSV66651553; called by muse, mutect2, varscan2
- BPIFB3 | c.915C>T p.T305= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV64957609; called by muse, mutect2, varscan2
- CPT1B | c.2318G>A p.*773= | Silent (SNP) | VAF 21/108 reads (19%) | catalogued as COSV56417604; called by muse, mutect2, varscan2
- CSMD2 | c.6024C>T p.I2008= | Silent (SNP) | VAF 30/133 reads (23%) | catalogued as COSV53929873; called by muse, mutect2, varscan2
- DHCR7 | c.840C>T p.Y280= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs148468879, COSV100831888; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- DOC2A | c.849C>A p.V283= | Silent (SNP) | VAF 18/115 reads (16%) | catalogued as COSV58751936; called by muse, mutect2, varscan2
- DYRK2 | c.1222C>T p.L408= (on ENST00000344096 / NM_006482.3; = p.L335= on NM_003583.4) | Silent (SNP) | VAF 9/108 reads (8%) | catalogued as COSV100165263, COSV100165276; called by muse, mutect2
- EHMT1 | c.3768C>T p.C1256= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV66044779; called by muse, mutect2, varscan2
- FLT4 | c.2997A>G p.Q999= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV56114157; called by muse, mutect2, varscan2
- HEXIM1 | c.477G>A p.K159= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV60177258, COSV60177276; called by muse, mutect2, varscan2
- INSYN2A | c.570C>G p.V190= | Silent (SNP) | VAF 15/181 reads (8%) | catalogued as COSV99728902; called by muse, mutect2
- IQCG | c.1080A>G p.Q360= | Silent (SNP) | VAF 127/1132 reads (11%) | catalogued as COSV54563542, COSV54564228; called by muse, mutect2, varscan2
- LGR6 | c.2394G>T p.L798= (on ENST00000367278 / NM_001017403.1; = p.L746= on NM_021636.3) | Silent (SNP) | VAF 54/94 reads (57%) | catalogued as COSV55160611; called by muse, mutect2, varscan2
- MARCHF6 | c.1587G>A p.L529= | Silent (SNP) | VAF 28/115 reads (24%) | catalogued as COSV56883524; called by muse, mutect2, varscan2
- MEGF8 | c.1383G>T p.V461= | Silent (SNP) | VAF 23/129 reads (18%) | catalogued as COSV52091902; called by muse, mutect2, varscan2
- MTMR10 | c.1452C>G p.S484= | Silent (SNP) | VAF 68/174 reads (39%) | catalogued as COSV58728173, COSV58728861; called by muse, mutect2, varscan2
- MYO15A | c.10545C>A p.A3515= | Silent (SNP) | VAF 94/163 reads (58%) | catalogued as COSV52760091; called by muse, mutect2, varscan2
- NPHS2 | c.942C>T p.G314= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as rs1229820034, COSV62635850; called by muse, mutect2, varscan2
- OTUD7B | c.141C>T p.V47= | Silent (SNP) | VAF 24/250 reads (10%) | catalogued as COSV100967492; called by muse, mutect2
- PACS1 | c.705C>T p.H235= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV57698617; called by muse, mutect2, varscan2
- PLPPR2 | c.9A>G p.G3= | Silent (SNP) | VAF 60/173 reads (35%) | called by muse, mutect2, varscan2
- PQBP1 | c.633C>T p.D211= | Silent (SNP) | VAF 40/237 reads (17%) | catalogued as rs781873995, COSV54429666; ClinVar: likely benign; called by muse, mutect2, varscan2
- RAD54L | c.813C>T p.L271= | Silent (SNP) | VAF 16/206 reads (8%) | catalogued as COSV100914782; called by muse, mutect2
- SEMA6B | c.666C>T p.D222= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as rs1568257713, COSV56704796; called by muse, mutect2, varscan2
- SNAP91 | c.1644C>T p.T548= | Silent (SNP) | VAF 62/135 reads (46%) | catalogued as COSV52127187; called by muse, mutect2, varscan2
- SPG7 | c.408G>A p.Q136= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs373144604; called by muse, mutect2, varscan2
- TDRD10 | c.687C>A p.T229= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as COSV52726044; called by muse, mutect2, varscan2
- TET1 | c.3186T>C p.D1062= | Silent (SNP) | VAF 43/113 reads (38%) | catalogued as COSV65386493; called by muse, mutect2, varscan2
- ZNF780A | c.1062T>C p.I354= | Silent (SNP) | VAF 34/281 reads (12%) | catalogued as COSV61815889; called by muse, mutect2, varscan2
